Somatic mutation profile of tumor specimen 0DSP27 from CCDI case PBCIJM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 13.2 years (4,837 days).
Specimen 0DSP27: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a7a531e-4c52-413b-9748-535a73675971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSP2J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6b4a103-ce8d-4fa0-afb3-da5cacf65c62

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.267del p.S90Pfs*33 | Frame Shift Del (DEL) | VAF 89/320 reads (28%) | catalogued as rs587783062; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADAM2 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 68/577 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs781759811, COSV55860004; called by muse, mutect2, varscan2
- MRC2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 125/817 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.765); catalogued as rs757362633, COSV57639515; called by muse, mutect2, varscan2
- MUC12 | c.8076del p.T2693Pfs*93 (on ENST00000379442; = p.T2550Pfs*93 on NM_001164462.1) | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs1554342786; called by mutect2, varscan2
- NPHS1 | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 173/840 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.297); catalogued as rs769019215, CD024189; called by muse, mutect2, varscan2
- OPLAH | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 120/810 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs781859755; called by muse, mutect2, varscan2
- PCDHGA10 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 165/897 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs756653393, COSV54010114; called by muse, mutect2, varscan2
- SLC2A9 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 94/626 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.936); catalogued as COSV99304850; called by muse, varscan2
- CLTCL1 | c.3628A>G p.M1210V | Missense Mutation (SNP) | VAF 39/620 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2
- SLCO1B3 | c.1760C>A p.A587D | Missense Mutation (SNP) | VAF 77/608 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MRPL52 | c.158-41C>A | Intron (SNP) | VAF 48/184 reads (26%) | called by muse, mutect2, varscan2
